Somatic mutation profile of tumor specimen TCGA-AP-A1DM-01A (aliquot TCGA-AP-A1DM-01A-21D-A135-09) from TCGA case TCGA-AP-A1DM, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 60.9 years (22,239 days).
Specimen TCGA-AP-A1DM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96706fa2-db3d-4c12-b58d-8ac36b00082c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A1DM-10A (Blood Derived Normal), aliquot TCGA-AP-A1DM-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/143a9c8f-a778-4e59-9678-f476735624c0

The open-access MAF lists 431 somatic variants for this specimen: 330 protein-altering or splice-affecting, 92 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 92, Frame Shift Del 88, Nonsense Mutation 16, Frame Shift Ins 14, RNA 6, In Frame Del 5, Splice Site 4, Splice Region 4, Intron 2, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSF4 | c.965del p.P322Rfs*74 (on ENST00000521374 / NM_001040667.3; = p.P292Rfs*74 on NM_001538.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | catalogued as rs776129797; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- IQSEC2 | c.854del p.P285Lfs*21 (on ENST00000642864 / NM_001111125.3; = p.P80Lfs*21 on NM_015075.2) | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs782460038; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2033del p.P678Rfs*10 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as rs587781807, CX1511110; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PYGM | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 37/100 reads (37%) | catalogued as rs119103255, CM981688, COSV51214780; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC29A3 | c.1045del p.L349Sfs*56 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs869025176; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACAT2 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100887119; called by muse, mutect2
- ADAMTS3 | c.3607T>G p.L1203V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99710735; called by muse, mutect2, varscan2
- ADAMTS3 | c.1067del p.L356* | Frame Shift Del (DEL) | VAF 40/113 reads (35%) | catalogued as rs1424429467; called by mutect2, pindel, varscan2
- ADGRG6 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV99746689; called by muse, mutect2, varscan2
- AGAP1 | c.2354C>T p.A785V (on ENST00000304032 / NM_001037131.3; = p.A732V on NM_014914.5) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs766225211, COSV100364615; called by muse, mutect2, varscan2
- AGRN | c.3003del p.G1002Afs*38 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | catalogued as rs763573703; called by mutect2, varscan2
- AL592490.1 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV101308141, COSV69427504; called by muse, mutect2, varscan2
- ALYREF | c.575T>G p.I192S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100485817; called by muse, mutect2, varscan2
- AMOTL2 | c.1960C>A p.P654T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99850617; called by muse, mutect2, varscan2
- ANAPC4 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as rs745448023, COSV100193945; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs749182271; called by mutect2, varscan2
- ANXA6 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); catalogued as rs781123987, COSV100636862; called by muse, mutect2, varscan2
- AOC1 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs780989863, COSV100710723; called by muse, mutect2
- AP2A2 | c.170del p.K57Sfs*24 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs753029866; called by mutect2, varscan2
- ARHGAP4 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as rs201193891, COSV61687206; called by muse, mutect2
- ARRDC1 | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.82); catalogued as COSV58379954; called by muse, mutect2, varscan2
- ATRNL1 | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV100744845; called by muse, mutect2, varscan2
- BCL9L | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866249341, COSV52683035; called by muse, mutect2, varscan2
- BTBD16 | c.1263G>T p.Q421H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99584660; called by muse, mutect2, varscan2
- C19orf73 | c.214T>C p.S72P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.276); catalogued as COSV99674430; called by muse, mutect2, varscan2
- CA9 | c.1312C>A p.Q438K | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.34); PolyPhen benign (0.444); catalogued as COSV100253159; called by muse, mutect2, varscan2
- CABIN1 | c.4072G>A p.D1358N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54080679; called by muse, mutect2, varscan2
- CAMK4 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as COSV99998828; called by muse, mutect2, varscan2
- CARM1 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV53404227; called by muse, mutect2, varscan2
- CCR9 | c.613G>A p.D205N (on ENST00000357632 / NM_031200.3; = p.D193N on NM_006641.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201973846, COSV62940230; called by muse, mutect2, varscan2
- CDC27 | c.2036A>G p.Q679R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99294609; called by muse, mutect2, varscan2
- CDR2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs780275569, COSV99193507; called by muse, mutect2, varscan2
- CEACAM18 | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV101140295; called by muse, mutect2, varscan2
- CELF4 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV100611459; called by mutect2, varscan2
- CHEK1 | c.646C>G p.Q216E | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as COSV99629575; called by muse, mutect2, varscan2
- CIT | c.5060G>A p.G1687D | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV55878855; called by muse, mutect2, varscan2
- CKB | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV100818920; called by muse, mutect2, varscan2
- CLEC18A | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs1351951790, COSV99846909; called by mutect2, varscan2
- CLEC3B | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs756022176, COSV99944534; called by muse, mutect2
- CNTNAP2 | c.2368C>T p.R790C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs200089329, COSV100665013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COX6A2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99791354; called by muse, mutect2, varscan2
- CPEB1 | c.898C>T p.L300F (on ENST00000617958; = p.L240F on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99917589; called by muse, mutect2, varscan2
- CRB1 | c.3563A>G p.H1188R | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100957801; called by muse, mutect2, varscan2
- CREB3L4 | c.577_579del p.E193del | In Frame Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs769844271; called by pindel, varscan2
- CSMD2 | c.24del p.G9Afs*303 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | catalogued as rs1557465436; called by mutect2, pindel, varscan2
- CST8 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55671597, COSV99849945, COSV99850115; called by muse, mutect2, varscan2
- CSTF2 | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV100802944; called by muse, mutect2, varscan2
- CTCF | c.1999+1G>A p.X667_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV50464417, COSV50506802; called by muse, mutect2, varscan2
- CUTC | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as rs758173583, COSV100976152; called by muse, mutect2, varscan2
- DACT1 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs1322099910, COSV60022638; called by muse, mutect2, varscan2
- DAGLA | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.296); catalogued as COSV57193778, COSV57197770; called by muse, mutect2, varscan2
- DCHS1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.33); catalogued as rs200795531, COSV55031852; called by muse, mutect2, varscan2
- DDX39B | c.355A>T p.M119L | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100795190; called by muse, mutect2, varscan2
- DENND2B | c.2389T>C p.C797R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100567386; called by muse, mutect2, varscan2
- DENND5B | c.2669A>G p.Q890R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.216); catalogued as COSV100171243; called by muse, mutect2, varscan2
- DHX57 | c.3490C>T p.R1164* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as rs1374355575, COSV99769344; called by muse, mutect2, varscan2
- DIAPH3 | c.2101G>A p.E701K (on ENST00000400324 / NM_001042517.2; = p.E438K on NM_030932.3) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.575); catalogued as COSV99933222; called by muse, mutect2, varscan2
- DIO3 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs762013346, COSV100832088; called by muse, mutect2, varscan2
- DNER | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs774454579, COSV100518794; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 28/62 reads (45%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DRICH1 | c.594A>T p.E198D | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.801); catalogued as COSV58503113; called by muse, mutect2, varscan2
- ECSCR | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV101579660; called by muse, mutect2, varscan2
- EFNB1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99214786; called by muse, mutect2, varscan2
- EGR4 | c.1099G>A p.G367R (on ENST00000545030; = p.G264R on NM_001965.4) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as rs775454359, COSV101474233; called by muse, mutect2, varscan2
- EHBP1L1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764167148, COSV57079108; called by muse, varscan2
- EPAS1 | c.1421G>C p.S474T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs1459319402, COSV55384152; called by muse, mutect2, varscan2
- EPN1 | c.1469G>A p.R490Q (on ENST00000270460 / NM_001321263.1; = p.R464Q on NM_013333.3) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs765609502, COSV50045775; called by muse, mutect2, varscan2
- ESPL1 | c.2827C>A p.H943N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99229167; called by muse, mutect2, varscan2
- ESPL1 | c.5712G>T p.W1904C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99228763; called by muse, mutect2, varscan2
- EXOC2 | c.25dup p.L9Pfs*9 | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | catalogued as rs748159069; called by mutect2, varscan2
- EXOC8 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.132); catalogued as COSV99149650; called by muse, mutect2, varscan2
- F8 | c.2916G>T p.M972I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV100811430; called by muse, mutect2, varscan2
- FAIM2 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs201471992, COSV57741782; called by muse, mutect2, varscan2
- FAM120B | c.1598C>A p.P533H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.946); catalogued as rs747036956, COSV99379207; called by muse, mutect2, varscan2
- FAM189B | c.854del p.P285Lfs*36 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | catalogued as COSV56944898; called by mutect2, pindel, varscan2
- FAM20B | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs778279832, COSV99762259; called by muse, mutect2, varscan2
- FAM83B | c.1163G>T p.S388I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100174297; called by muse, mutect2, varscan2
- FAM83B | c.2247G>T p.E749D | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100174299; called by muse, mutect2, varscan2
- FAT2 | c.3575-1G>T p.X1192_splice | Splice Site (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99942388; called by muse, mutect2, varscan2
- FAT4 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs763440848, COSV101272239; called by muse, mutect2, varscan2
- FCAR | c.575G>T p.R192M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100629041; called by muse, mutect2, varscan2
- FCRL2 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as rs200327020, COSV100829880; called by muse, mutect2
- FEZF1 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | catalogued as COSV100484474; called by muse, mutect2, varscan2
- FOXL1 | c.157A>G p.S53G | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100206211; called by muse, mutect2
- FOXP1 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs1454411756, COSV100561416; called by muse, mutect2, varscan2
- GABRG2 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs778814579, COSV62720746; called by muse, mutect2, varscan2
- GBP3 | c.1617G>T p.Q539H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV99352450; called by muse, mutect2, varscan2
- GPR63 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); catalogued as COSV100013262; called by muse, mutect2
- GPSM1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs782266782, COSV100696582; called by muse, mutect2, varscan2
- GRIN2A | c.4021del p.S1341Afs*56 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as COSV58051797; called by mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 54/72 reads (75%) | catalogued as rs754199513; called by mutect2, varscan2
- HEATR5B | c.4960C>T p.P1654S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs778722074, COSV51852820; called by muse, mutect2, varscan2
- HIRA | c.2039C>T p.A680V | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99600149; called by muse, mutect2, varscan2
- IGHV1-24 | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1555470132; called by muse, mutect2, varscan2
- IKBIP | c.775A>G p.R259G | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100689750; called by muse, mutect2, varscan2
- IL34 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV99851796; called by muse, mutect2, varscan2
- INPP5K | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100233687; called by muse, mutect2, varscan2
- INSM2 | c.1605dup p.S536* | Frame Shift Ins (INS) | VAF 7/30 reads (23%) | catalogued as rs756928018; called by mutect2, varscan2
- INTS14 | c.1288dup p.T430Nfs*6 (on ENST00000313182 / NM_001366360.2; = p.T351Nfs*6 on NM_001136043.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 32/115 reads (28%) | catalogued as rs781635472; called by mutect2, pindel, varscan2
- INTS7 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100877466; called by muse, mutect2, varscan2
- ITFG1 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100278612; called by muse, mutect2, varscan2
- ITGAM | c.1441del p.H481Ifs*45 (on ENST00000648685 / NM_001145808.2; = p.H481Ifs*44 on NM_000632.4) | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | catalogued as rs1303173835; called by mutect2, pindel, varscan2
- ITPR3 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs916427217, COSV65413547; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | catalogued as rs755650243; called by pindel, varscan2*
- KANK2 | c.205del p.R69Afs*2 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as COSV100763392; called by mutect2, pindel, varscan2
- KATNBL1 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV99854325; called by muse, mutect2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | catalogued as rs749990720; called by mutect2, varscan2
- KIF5B | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs756101109, COSV100191752; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs754171400, COSV63285253; called by mutect2, pindel, varscan2
- KLRG2 | c.1005G>T p.Q335H | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100572490; called by muse, mutect2
- KMT2B | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs757528647, COSV99385985; called by muse, mutect2, varscan2
- KNDC1 | c.3779C>T p.A1260V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs776390728, COSV100464298; called by muse, mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs750491454; called by mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 28/65 reads (43%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | catalogued as rs748712732; called by mutect2, varscan2
- LOXL1 | c.1271A>G p.Q424R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV99985280; called by muse, mutect2, varscan2
- LY75 | c.1120C>G p.L374V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV99716288; called by muse, mutect2, varscan2
- MAGED1 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV100431504; called by muse, mutect2, varscan2
- MAN2B2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.21); catalogued as rs1246175822, COSV99577280; called by muse, mutect2, varscan2
- MBD6 | c.2135C>T p.T712M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as rs372081138; called by muse, mutect2, varscan2
- MET | c.3011G>A p.R1004Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100577151, COSV59256534; called by muse, mutect2, varscan2
- MICAL3 | c.1685C>A p.P562H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99261054; called by muse, mutect2, varscan2
- MICU1 | c.626A>G p.Y209C (on ENST00000361114 / NM_001195518.2; = p.Y215C on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100741730; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 17/35 reads (49%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MLH3 | c.1739A>T p.E580V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV99470057; called by muse, mutect2, varscan2
- MTR | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100855947; called by muse, mutect2, varscan2
- MUC16 | c.32528del p.F10843Sfs*11 | Frame Shift Del (DEL) | VAF 34/93 reads (37%) | catalogued as COSV67467225; called by mutect2, pindel, varscan2
- MUC2 | c.3128G>A p.R1043H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs766155495; called by muse, mutect2, varscan2
- MUC5AC | c.15514G>A p.V5172I | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.548); catalogued as rs748370307, COSV100611386; called by muse, mutect2, varscan2
- MYBPC2 | c.2505G>A p.A835= | Splice Region (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100731974, COSV63094020; called by muse, mutect2, varscan2
- MYO5C | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99954546; called by muse, mutect2, varscan2
- MYOM1 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1229084764, COSV99866150; called by muse, mutect2, varscan2
- NDRG4 | c.44A>G p.Y15C (on ENST00000570248 / NM_001378344.1; = p.Y47C on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99261957; called by muse, varscan2
- NEFM | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV55332393; called by muse, mutect2
- NELFB | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs369149566; called by muse, mutect2
- NFKB1 | c.955A>T p.K319* (on ENST00000394820 / NM_001382627.1; = p.K320* on NM_003998.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV99896960; called by muse, varscan2
- NID1 | c.747G>T p.L249F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99937336; called by muse, mutect2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs145147241; called by mutect2, varscan2
- NLRC5 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs780658848, COSV52650308; called by muse, mutect2, varscan2
- NMUR2 | c.995G>C p.R332P | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as COSV54917923, COSV54920182, COSV99676780; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NR2C2 | c.1667A>G p.N556S (on ENST00000393102; = p.N575S on NM_003298.5) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100038411; called by muse, mutect2, varscan2
- NRK | c.4645G>T p.G1549C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99687347, COSV99687891; called by muse, mutect2, varscan2
- OCRL | c.2083C>T p.R695* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as CM983299, COSV100843289; called by muse, mutect2, varscan2
- OLFM3 | c.1081G>A p.A361T (on ENST00000338858 / NM_001288821.1; = p.A341T on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.425); catalogued as COSV100129217; called by muse, mutect2, varscan2
- OLFML2B | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as rs1219748120, COSV99668286; called by muse, mutect2, varscan2
- OPA3 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99840935; called by muse, mutect2, varscan2
- OR2C1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758515140, COSV100514906, COSV59239528; called by muse, mutect2, varscan2
- OR51B5 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV100332507; called by muse, mutect2, varscan2
- OSBPL1A | c.1909C>T p.R637* (on ENST00000319481 / NM_080597.4; = p.R124* on NM_018030.4) | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as rs932076204, COSV60195481; called by muse, mutect2, varscan2
- OSGIN2 | c.441G>T p.M147I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV99858196; called by muse, mutect2, varscan2
- PABPC5 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV100442272; called by muse, mutect2, varscan2
- PADI3 | c.1374del p.V459Wfs*17 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | catalogued as rs747531633; called by mutect2, pindel, varscan2
- PAPPA | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.877); catalogued as COSV100072545, COSV60287541; called by muse, mutect2, varscan2
- PAX8 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99639356; called by muse, mutect2, varscan2
- PCCB | c.1447C>G p.Q483E | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs149527841; called by muse, mutect2, varscan2
- PCDH1 | c.660G>T p.Q220H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99745929; called by muse, mutect2, varscan2
- PCLO | c.9653G>A p.R3218H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as rs376658400, COSV61643055; called by muse, mutect2, varscan2
- PCSK4 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756315905, COSV99278573; called by muse, mutect2, varscan2
- PIK3R1 | c.1344del p.K448Nfs*32 (on ENST00000521381 / NM_181523.3; = p.K178Nfs*32 on NM_181504.4) | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs1289537429; called by mutect2, pindel, varscan2
- PKHD1 | c.9283G>A p.V3095I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.427); catalogued as rs768508521, COSV100582467, COSV61859100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLG | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374903528; called by muse, mutect2, varscan2
- PLK4 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99584568; called by muse, mutect2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PNPLA7 | c.2921G>A p.R974Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs771308200, COSV53008917; called by muse, mutect2, varscan2
- POLE | c.3962G>A p.R1321K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100266019; called by muse, mutect2, varscan2
- POLR1A | c.4849G>A p.A1617T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367979854; called by muse, mutect2, varscan2
- PPWD1 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as COSV99731225; called by muse, mutect2, varscan2
- PRAMEF6 | c.1249dup p.R417Pfs*5 | Frame Shift Ins (INS) | VAF 38/272 reads (14%) | catalogued as rs1553173106; called by mutect2, varscan2
- PSAPL1 | c.1466G>A p.W489* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as rs751416918, COSV100040431; called by muse, mutect2, varscan2
- PSMB11 | c.251T>C p.I84T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs778084561, COSV101273439; called by muse, mutect2, varscan2
- PTCH1 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.29); catalogued as rs762040036, COSV100108122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.115G>C p.A39P | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM083057, CM1513156, COSV64298926, COSV64303687; called by muse, mutect2, varscan2
- PTEN | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as CM142084, COSV64288921, COSV64307012; called by muse, mutect2, varscan2
- PUDP | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as rs975694336, COSV66904973; called by muse, mutect2, varscan2
- R3HDML | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407082; called by muse, mutect2, varscan2
- RABGAP1L | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.094); catalogued as COSV99269302; called by muse, mutect2, varscan2
- RAD52 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99942496; called by muse, mutect2, varscan2
- RAE1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); catalogued as rs753152734, COSV100982396; called by muse, mutect2, varscan2
- RAPGEF4 | c.2793G>A p.M931I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1202883372, COSV99910320; called by muse, mutect2, varscan2
- RAVER1 | c.1097dup p.A367Sfs*83 | Frame Shift Ins (INS) | VAF 12/91 reads (13%) | catalogued as rs768618392; called by mutect2, varscan2
- RBM33 | c.2887G>A p.V963M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.104); catalogued as rs371777379, COSV56637713; called by muse, mutect2, varscan2
- RELN | c.4220A>G p.Y1407C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100633243; called by muse, mutect2, varscan2
- RFPL4B | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV101480688; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS13 | c.64A>G p.N22D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV101232217; called by muse, mutect2, varscan2
- RNH1 | c.249del p.S84Pfs*7 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | catalogued as rs1295211903; called by mutect2, pindel, varscan2
- ROBO2 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as rs1271172110, COSV59915814, COSV59929302; called by muse, mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs752898741; called by mutect2, varscan2
- RPL36A | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs1427877173, COSV65718091; called by muse, mutect2, varscan2
- RRP9 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs372092049; called by muse, mutect2, varscan2
- RYR3 | c.14548T>A p.C4850S (on ENST00000389232; = p.C4851S on NM_001036.6) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); catalogued as COSV100145444; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SALL4 | c.2461+2T>C p.X821_splice | Splice Site (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99409409; called by muse, mutect2, varscan2
- SAMD11 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs770001898, COSV100574587; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCMH1 | c.1850G>A p.R617H (on ENST00000326197 / NM_001031694.2; = p.R548H on NM_012236.4) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143623408; called by muse, mutect2, varscan2
- SDHA | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV53773388; called by muse, mutect2
- SEC14L2 | c.801G>T p.K267N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100464464; called by muse, mutect2, varscan2
- SEMA5B | c.3323C>T p.P1108L | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.028); catalogued as COSV99530810; called by muse, mutect2
- SEMA6D | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1232623340, COSV60379148; called by muse, mutect2, varscan2
- SGSM2 | c.2207G>A p.G736D (on ENST00000426855 / NM_001098509.2; = p.G781D on NM_014853.3) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99280005; called by muse, mutect2, varscan2
- SHANK3 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs370831167; called by muse, mutect2, varscan2
- SIPA1L3 | c.2337del p.I780Sfs*21 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs748827733, COSV55912723; called by mutect2, varscan2
- SIPA1L3 | c.4075A>G p.R1359G | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV55919773, COSV99728238; called by muse, mutect2, varscan2
- SLC15A3 | c.1490G>A p.G497D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745812976, COSV99134709; called by muse, mutect2, varscan2
- SLC25A1 | c.631G>T p.G211W | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99310928; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A10 | c.3346T>G p.S1116A (on ENST00000446997 / NM_001354461.2; = p.S1086A on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.661); catalogued as COSV99763347; called by muse, mutect2, varscan2
- SLC9B1 | c.1372T>A p.S458T | Missense Mutation (SNP) | VAF 21/350 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as COSV99599450; called by muse, mutect2
- SMARCA2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as rs1158455540, COSV100570689; called by muse, mutect2, varscan2
- SMARCAD1 | c.1232A>G p.K411R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as COSV100758869; called by muse, varscan2
- SMG7 | c.2545del p.M849* | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs749889899; called by mutect2, varscan2
- SND1 | c.2410C>T p.P804S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100690139; called by muse, mutect2, varscan2
- SOX14 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60163242; called by muse, mutect2, varscan2
- SOX6 | c.2369C>T p.A790V (on ENST00000528429 / NM_001145819.2; = p.A763V on NM_017508.3) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100321834; called by muse, mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SOX9 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 51/109 reads (47%) | catalogued as COSV55427710; called by muse, mutect2, varscan2
- SPAG4 | c.411C>T p.S137= | Splice Region (SNP) | VAF 6/29 reads (21%) | catalogued as rs1446601175, COSV100958293; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 7/15 reads (47%) | catalogued as COSV54965656; called by mutect2, varscan2
- ST13 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99344085; called by muse, mutect2, varscan2
- STAB2 | c.4522G>A p.G1508S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101185857, COSV66337155; called by muse, mutect2, varscan2
- STRADA | c.686T>C p.V229A (on ENST00000336174 / NM_001363786.1; = p.V192A on NM_153335.6) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99835072; called by muse, mutect2, varscan2
- SV2B | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV100370567; called by muse, mutect2, varscan2
- SYMPK | c.3205C>T p.P1069S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV99679707; called by muse, mutect2, varscan2
- SYMPK | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99841595; called by muse, mutect2, varscan2
- SYNGAP1 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773495243, COSV99538191; called by muse, mutect2, varscan2
- SYNGAP1 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99538197; called by muse, mutect2, varscan2
- SYNM | c.4267G>A p.V1423M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as rs782506569, COSV100018605; called by muse, mutect2, varscan2
- SYT3 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs763235130, COSV100143979; called by muse, mutect2, varscan2
- SZT2 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as COSV100161680; called by muse, mutect2, varscan2
- TAFA3 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100721450; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs763321097; called by mutect2, varscan2
- TEX2 | c.2858C>T p.A953V (on ENST00000583097 / NM_001288733.2; = p.A960V on NM_018469.5) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99366979; called by muse, mutect2, varscan2
- TEX47 | c.342T>A p.Y114* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV51879610, COSV51879791, COSV99787243; called by muse, mutect2, varscan2
- THSD7A | c.1552T>C p.W518R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101448628; called by muse, mutect2, varscan2
- TLE3 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs766703742, COSV100450268; called by muse, mutect2, varscan2
- TMCO4 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs370292527; called by muse, mutect2, varscan2
- TMEFF2 | c.908del p.K303Rfs*19 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | catalogued as rs1553506636, COSV55829678; called by mutect2, pindel, varscan2
- TNFRSF14 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100859115, COSV63187608; called by muse, mutect2, varscan2
- TNFRSF1A | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as COSV99369589; called by muse, mutect2, varscan2
- TPH2 | c.1298+2T>C p.X433_splice | Splice Site (SNP) | VAF 17/44 reads (39%) | catalogued as COSV61590994; called by muse, mutect2, varscan2
- TRIM17 | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV99694647; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | catalogued as rs752676391; called by mutect2, varscan2
- TRRAP | c.10871C>T p.A3624V (on ENST00000359863 / NM_001244580.1; = p.A3595V on NM_003496.3) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV100705403; called by muse, mutect2, varscan2
- TTC3 | c.1244A>C p.E415A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.629); catalogued as COSV100695312; called by muse, mutect2, varscan2
- TTC7B | c.2018C>T p.S673L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs771712271, COSV100127738; called by muse, mutect2, varscan2
- TTN | c.95771C>T p.A31924V (on ENST00000591111; = p.A24500V on NM_003319.4) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | PolyPhen benign (0.015); catalogued as COSV100605063; called by muse, mutect2, varscan2
- TTN | c.87986C>T p.A29329V (on ENST00000591111; = p.A21905V on NM_003319.4) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | PolyPhen benign (0.077); catalogued as COSV100605064; called by muse, mutect2, varscan2
- UGT2A2 | c.489C>G p.I163M | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV99684148; called by muse, mutect2, varscan2
- UNC13C | c.6052A>G p.T2018A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1205190785, COSV99515063; called by muse, mutect2, varscan2
- USP8 | c.226del p.R76Dfs*36 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs1567603601; called by mutect2, pindel, varscan2
- VPS9D1 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV101231982; called by muse, mutect2, varscan2
- WASHC2C | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100313911; called by muse, mutect2, varscan2
- WDR33 | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs749028157, COSV59257832; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WIZ | c.2627G>A p.R876Q (on ENST00000673675 / NM_001371589.1; = p.R139Q on NM_021241.3) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs376481490; called by muse, mutect2, varscan2
- WNK4 | c.3700del p.V1234* | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs1453923832; called by mutect2, pindel, varscan2
- WWC3 | c.1733T>G p.F578C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101081330; called by muse, mutect2, varscan2
- XKR6 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.93); catalogued as rs761510924, COSV100440496; called by muse, mutect2, varscan2
- YBX2 | c.506A>C p.K169T | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV99142690; called by muse, mutect2, varscan2
- YPEL2 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100445255; called by muse, mutect2, varscan2
- ZBTB4 | c.11del p.P4Lfs*4 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | catalogued as rs765991494; called by mutect2, varscan2
- ZBTB43 | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100991333; called by muse, mutect2, varscan2
- ZNF423 | c.1837C>A p.P613T (on ENST00000563137 / NM_001379286.1; = p.P605T on NM_015069.4) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV52182951; called by muse, mutect2, varscan2
- ZNF564 | c.132A>G p.G44= | Splice Region (SNP) | VAF 20/41 reads (49%) | catalogued as rs1024922724, COSV100213076, COSV100213353, COSV59434102; called by muse, mutect2, varscan2
- ZNF619 | c.1186A>T p.S396C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as COSV100123143; called by muse, mutect2, varscan2
- ZNF670 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100829222; called by muse, mutect2, varscan2
- ZNF99 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV101233789; called by muse, mutect2, varscan2
- ZNFX1 | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1279181982, COSV100870800; called by muse, mutect2, varscan2
- ABI1 | c.1097del p.P366Lfs*7 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.2287del p.T763Qfs*14 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- ARFGAP3 | c.1143del p.E382Rfs*10 | Frame Shift Del (DEL) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
- ARFGEF3 | c.32_34del p.E11del | In Frame Del (DEL) | VAF 4/18 reads (22%) | called by pindel, varscan2
- ARID1A | c.4555del p.Q1519Rfs*8 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- ARRDC3 | c.1138_1141del p.F380Hfs*40 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- ARV1 | c.517_518del p.K173Afs*14 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by mutect2, varscan2
- ASTL | c.285del p.M96Wfs*132 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.1707del p.V570* | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, varscan2
- CCDC170 | c.1930_1932del p.E644del | In Frame Del (DEL) | VAF 8/17 reads (47%) | called by mutect2, varscan2
- CCDC39 | c.1158dup p.D387Rfs*18 | Frame Shift Ins (INS) | VAF 26/75 reads (35%) | called by mutect2, pindel, varscan2
- CNOT9 | c.200del p.L67Yfs*5 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- COL2A1 | c.3137dup p.G1047Wfs*11 | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- CPS1 | c.4401del p.Q1468Rfs*2 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | called by mutect2, pindel, varscan2
- CUEDC2 | c.366_368del p.E123del | In Frame Del (DEL) | VAF 16/37 reads (43%) | called by pindel, varscan2
- CUX1 | c.3164del p.P1055Lfs*7 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | called by mutect2, pindel, varscan2
- DAGLB | c.1219-3del | Splice Region (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- DMTN | c.364del p.R122Gfs*109 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- DNAH11 | c.10071del p.A3358Qfs*12 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- DZIP1 | c.1852_1853del p.S618Cfs*27 (on ENST00000347108; = p.S599Cfs*27 on NM_014934.5) | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | called by mutect2, pindel, varscan2
- DZIP1 | c.337dup p.V113Gfs*92 | Frame Shift Ins (INS) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- EFCAB7 | c.1293del p.F431Lfs*3 | Frame Shift Del (DEL) | VAF 23/56 reads (41%) | called by mutect2, pindel, varscan2
- EPHA8 | c.1802del p.P601Rfs*82 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- FAM13B | c.2346del p.F782Lfs*18 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- FRMD7 | c.579dup p.A194Rfs*3 | Frame Shift Ins (INS) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- FSTL5 | c.1372del p.Y458Mfs*7 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- GABRB3 | c.508del p.L170Wfs*66 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- GLIS2 | c.220del p.S74Qfs*177 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.1135del p.R379Gfs*2 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel, varscan2
- HDAC4 | c.2703del p.M902Wfs*55 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- HERC1 | c.13153del p.Q4385Sfs*5 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- HRH4 | c.508del p.S170Rfs*15 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, varscan2
- IFRD1 | c.916del p.Y306Mfs*7 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- KLRK1 | c.419_420del p.K140Rfs*7 | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- KMT2B | c.7345del p.A2449Pfs*11 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- LAMC3 | c.1347del p.C450Afs*83 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- MLLT6 | c.2158G>A p.V720M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2
- MTUS1 | c.3375del p.A1126Qfs*3 (on ENST00000262102 / NM_001363061.1; = p.A292Qfs*3 on NM_020749.4) | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- NEIL1 | c.570del p.F191Lfs*20 | Frame Shift Del (DEL) | VAF 11/23 reads (48%) | called by mutect2, pindel, varscan2
- NRK | c.2060_2061del p.K687Sfs*26 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- NUP210L | c.5594del p.P1865Lfs*4 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | called by mutect2, pindel, varscan2
- OOSP2 | c.270dup p.Q91Sfs*14 | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1709_1714dup p.L570_I571dup (on ENST00000521381 / NM_181523.3; = p.L300_I301dup on NM_181504.4) | In Frame Ins (INS) | VAF 20/43 reads (47%) | called by mutect2, varscan2
- PLAT | c.94dup p.R32Kfs*13 | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- PMS2 | c.793_795del p.N265del | In Frame Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- PRR3 | c.500del p.K167Rfs*38 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
- SERINC4 | c.1476del p.T493Pfs*9 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- SHC2 | c.584del p.G195Dfs*26 | Frame Shift Del (DEL) | VAF 35/100 reads (35%) | called by mutect2, pindel, varscan2
- SIPA1L1 | c.172dup p.R58Pfs*3 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | called by mutect2, varscan2
- SPAG1 | c.324dup p.E109Rfs*4 | Frame Shift Ins (INS) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- STS | c.553del p.L185Cfs*24 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- SUGP2 | c.763del p.I255Yfs*4 | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | called by mutect2, varscan2
- TIMM50 | c.631del p.H211Mfs*21 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- TLX3 | c.758del p.N253Tfs*150 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- TNFAIP3 | c.1368del p.P457Lfs*20 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- TRMT13 | c.627del p.V210Ffs*5 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, varscan2
- TUBGCP5 | c.2458del p.I820Ffs*12 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- TUT1 | c.87del p.S30Afs*15 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.5037dup p.L1680Tfs*7 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- ABHD14A-ACY1 | c.918C>T p.C306= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs199990594, COSV56472582; called by muse, mutect2, varscan2
- ACE | c.1266C>T p.D422= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs908511692, COSV99326782; called by mutect2, varscan2
- ANKRD11 | c.4530G>A p.P1510= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs142410261, COSV56371568; called by muse, mutect2, varscan2
- ARX | c.171C>T p.R57= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV100984045, COSV66874727; called by muse, varscan2
- ASB2 | c.585C>T p.H195= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs753571518, COSV60110833; called by muse, mutect2
- ATXN2 | c.3585C>T p.H1195= (on ENST00000550104; = p.H1035= on NM_002973.4) | Silent (SNP) | VAF 57/114 reads (50%) | catalogued as rs534955585, COSV57981211; called by muse, mutect2, varscan2
- BRD1 | c.636C>T p.D212= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs759394790, COSV53457209; called by muse, mutect2, varscan2
- C11orf42 | c.111A>G p.V37= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs774733161, COSV56411570; called by muse, mutect2, varscan2
- C1QTNF1 | c.678C>T p.G226= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs72853332, COSV100189844; called by muse, mutect2, varscan2
- CACNA2D4 | c.2559C>T p.G853= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1009598544, COSV99765452; called by muse, mutect2, varscan2
- CD207 | c.810G>A p.T270= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs782603589, COSV101338544; called by muse, mutect2, varscan2
- CDIPT | c.351T>C p.S117= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99570162; called by muse, mutect2, varscan2
- CDO1 | c.84C>T p.V28= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99164773; called by muse, mutect2, varscan2
- CFAP43 | c.1452G>A p.Q484= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99530595; called by muse, mutect2, varscan2
- CNTROB | c.588C>T p.R196= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100366438; called by muse, mutect2, varscan2
- COL7A1 | c.3819C>T p.D1273= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1190824941, COSV100095732; called by muse, mutect2, varscan2
- CRTC3 | c.1182G>A p.T394= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs199722697, COSV99185650; called by mutect2, varscan2
- CST2 | c.369C>T p.Y123= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs13041691, COSV59030346, COSV59030991; called by muse, mutect2, varscan2
- CTRB2 | c.246C>T p.D82= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1263998142, COSV100274696; called by mutect2, varscan2
- DNAAF1 | c.960C>T p.S320= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs560165442, COSV100533587, COSV57577521; called by muse, mutect2, varscan2
- DNAH11 | c.5295C>T p.Y1765= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs377687532; ClinVar: likely benign; called by muse, mutect2, varscan2
- EDC4 | c.1599C>A p.A533= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV100739057; called by muse, mutect2, varscan2
- EGFLAM | c.2352G>A p.A784= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs781049462, COSV100380159; called by muse, mutect2, varscan2
- FAM122B | c.666C>T p.S222= (on ENST00000370790 / NM_001166599.3; = p.S223= on NM_145284.5) | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs374337416, COSV99980264; called by muse, mutect2, varscan2
- FBXL7 | c.483C>T p.G161= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs1008945219, COSV100309536; called by muse, mutect2, varscan2
- FSIP1 | c.1278T>C p.S426= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100618039; called by muse, mutect2, varscan2
- GAB4 | c.1602G>A p.T534= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs913541210, COSV101271951; called by muse, mutect2, varscan2
- GCC2 | c.2241T>C p.N747= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100565381; called by muse, mutect2, varscan2
- GFRAL | c.324G>A p.V108= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100474959; called by mutect2, varscan2
- GP5 | c.99G>A p.A33= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV55467332; called by muse, mutect2, varscan2
- HDAC4 | c.174A>T p.S58= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV100613170, COSV61872583; called by muse, mutect2, varscan2
- HERC6 | c.981C>A p.A327= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV99910508; called by muse, mutect2, varscan2
- HIVEP3 | c.1593C>T p.T531= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs369367320; called by muse, mutect2, varscan2
- HM13 | c.978C>T p.C326= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV100159427; called by muse, mutect2, varscan2
- HNRNPCL1 | c.858C>T p.S286= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs148930640; called by muse, mutect2, varscan2
- HYDIN | c.13557C>T p.S4519= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs780996622, COSV101125013; called by muse, mutect2, varscan2
- IDO1 | c.78A>G p.P26= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1209315767, COSV99503265; called by muse, mutect2, varscan2
- IFT80 | c.684T>C p.H228= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100424620; called by muse, mutect2, varscan2
- INSRR | c.1527G>C p.L509= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100947372; called by muse, varscan2
- IQCN | c.3171C>T p.S1057= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs370353928; called by muse, mutect2, varscan2
- ITPR2 | c.3315C>T p.D1105= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs556908489, COSV101189932; called by muse, mutect2, varscan2
- ITPR3 | c.2175G>T p.V725= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100967231; called by muse, mutect2, varscan2
- KBTBD7 | c.1116T>C p.P372= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV101068078; called by muse, mutect2, varscan2
- KLF12 | c.1062C>T p.C354= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV66573714; called by muse, mutect2, varscan2
- KLRC4 | c.294A>C p.G98= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100511283; called by muse, mutect2, varscan2
- LCMT2 | c.141C>G p.R47= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV59790936; called by muse, mutect2, varscan2
- LDB3 | c.2001C>G p.T667= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV99555002, COSV99555946; called by muse, mutect2, varscan2
- LGALS7B | c.117C>T p.C39= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV59252430; called by muse, mutect2, varscan2
- LRBA | c.6786G>A p.L2262= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100841355; called by muse, mutect2, varscan2
- MARCHF4 | c.1143C>T p.I381= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV56107308, COSV99814244; called by muse, mutect2, varscan2
- MED12 | c.1173C>T p.G391= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV100377266; called by muse, mutect2, varscan2
- MGAM | c.1155C>T p.Y385= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs375809034; called by muse, mutect2, varscan2
- MYBPC3 | c.960C>T p.D320= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs369900803, COSV57024546; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH15 | c.87C>T p.A29= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs756712911, COSV99842914; called by muse, mutect2, varscan2
- NEDD9 | c.1575T>C p.C525= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV101060818; called by muse, mutect2, varscan2
- NLRP11 | c.2739T>A p.L913= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100789703; called by muse, mutect2, varscan2
- NPHP4 | c.1296T>C p.S432= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100976831; called by muse, mutect2, varscan2
- OAS1 | c.207C>T p.T69= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99177104; called by muse, mutect2, varscan2
- OBSCN | c.8115G>A p.V2705= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1015127859, COSV99476179; called by muse, mutect2
- PAQR5 | c.258G>A p.V86= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV100575444; called by muse, mutect2, varscan2
- PGAP4 | c.1068C>T p.C356= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100877815; called by muse, mutect2
- PIK3R6 | c.1950G>A p.V650= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs184716744; called by muse, mutect2, varscan2
- PLA2R1 | c.4221G>T p.L1407= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV51774953; called by muse, mutect2
- POLA2 | c.129C>T p.G43= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs779231718, COSV99640796; called by muse, mutect2, varscan2
- PPP1R10 | c.2412C>T p.G804= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs761924508, COSV64740264; called by muse, mutect2, varscan2
- PRDM9 | c.2397A>C p.T799= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV57014121; called by muse, mutect2, varscan2
- PRPF8 | c.3585C>T p.R1195= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100517366; called by muse, mutect2, varscan2
- PRRC2C | c.5799G>A p.Q1933= (on ENST00000367742; = p.Q1931= on NM_015172.4) | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100145060; called by muse, mutect2
- PSEN1 | c.288C>T p.V96= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99997760; called by muse, mutect2, varscan2
- PSMB8 | c.621C>A p.A207= (on ENST00000374882 / NM_148919.4; = p.A203= on NM_004159.5) | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100841166; called by muse, mutect2
- PTGFRN | c.2604C>T p.R868= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs763120740, COSV67797884; called by muse, mutect2, varscan2
- RAPGEF2 | c.45G>A p.Q15= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1199878452, COSV100030951; called by muse, mutect2, varscan2
- RASGRP1 | c.1849T>C p.L617= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs766589590, COSV100171871; called by muse, mutect2, varscan2
- RBMX | c.1161C>T p.G387= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV100284696; called by muse, mutect2
- SERINC2 | c.312G>A p.T104= (on ENST00000373709 / NM_178865.5; = p.T108= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs782389423, COSV101036809; called by muse, mutect2
- SETBP1 | c.2556G>A p.T852= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs150665941, COSV99954521; called by muse, mutect2, varscan2
- SLFN13 | c.1056C>T p.D352= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs760669215, COSV53192520; called by muse, mutect2, varscan2
- SPATA13 | c.1596T>C p.S532= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100542127; called by muse, mutect2, varscan2
- SPATS2L | c.1356G>T p.S452= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs773496243, COSV100660601; called by muse, mutect2, varscan2
- SPTBN1 | c.5172T>C p.H1724= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV100442321; called by muse, mutect2, varscan2
- SPTBN4 | c.231C>T p.R77= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100150594; called by muse, mutect2, varscan2
- TANC2 | c.1768C>T p.L590= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV101267349; called by muse, mutect2, varscan2
- THSD4 | c.2139G>A p.T713= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs764158675, COSV55978132, COSV99965114; called by muse, mutect2, varscan2
- TIAM2 | c.4521T>C p.P1507= (on ENST00000529824; = p.P1478= on NM_012454.3) | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99265328; called by muse, mutect2, varscan2
- TMTC4 | c.1003C>T p.L335= (on ENST00000376234 / NM_001350577.2; = p.L354= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100168600; called by muse, mutect2, varscan2
- TOPBP1 | c.1719C>T p.N573= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs1476922871, COSV99605170; called by muse, mutect2, varscan2
- TSGA10 | c.1932C>T p.A644= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs748720493, COSV61822580; called by muse, mutect2, varscan2
- YME1L1 | c.2295T>C p.L765= (on ENST00000326799 / NM_139312.3; = p.L708= on NM_014263.4) | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV58758236; called by muse, mutect2, varscan2
- ZFP37 | c.1059G>A p.Q353= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV100953234, COSV65288915; called by muse, mutect2, varscan2
- ZNF528 | c.372A>G p.Q124= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs201282092, COSV100846641; called by muse, mutect2, varscan2
- ZNF585B | c.477A>G p.V159= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100459388; called by muse, mutect2, varscan2
- ZNF786 | c.354T>C p.P118= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100302784, COSV60276140; called by muse, mutect2, varscan2
- CCDC159 | c.22-516G>A | Intron (SNP) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- CHCHD2P9 | n.174G>A | RNA (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- MEIS2 | c.1147+384G>T | Intron (SNP) | VAF 47/118 reads (40%) | catalogued as COSV99576194; called by muse, mutect2, varscan2
- PRR12 | chr19:49593354 G>A | 5'Flank (SNP) | VAF 22/57 reads (39%) | catalogued as rs368178393, COSV55870961; called by muse, mutect2, varscan2
- REXO1L1P | n.1535C>T | RNA (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2, varscan2
- SLC35E2A | n.843del | RNA (DEL) | VAF 19/117 reads (16%) | catalogued as COSV55803748; called by mutect2, pindel, varscan2
- SNORD116-4 | n.28del | RNA (DEL) | VAF 22/66 reads (33%) | catalogued as rs753149037; called by mutect2, varscan2
- SSPOP | n.8581del | RNA (DEL) | VAF 19/65 reads (29%) | catalogued as rs552397911; called by mutect2, pindel, varscan2
- TMEM183B | n.1128G>A | RNA (SNP) | VAF 16/56 reads (29%) | catalogued as rs1366562666; called by muse, mutect2, varscan2
